CCDI case PBCEBH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/6dfce1cd-f000-402c-9c03-ee274c38f18b

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 16.3 years (5,964 days).

Biospecimens (3 samples)
- Sample 0DPU2L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPU2O, 0DPU2X (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
